Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A161, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A161-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Site Code: Endometrium C54.1

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 A6 B1 C1 C2 D1 D2 E1 F1 G1 G2 G3
G4
Uterus (45.0 grams), right ovary (3.0 x 0.9 x 0.8 cm) with
7.4 cm
segment of right fallopian tube, left ovary (2.8 x 0.7 x
0.5 cm)
with 7.7 cm segment of left fallopian tube, left pelvic
lymph nodes,
right pelvic lymph nodes, and bilateral para-aortic lymph
nodes
(above and below the inferior mesenteric artery).

DIAGNOSIS:

Uterus, hysterectomy: FIGO grade I (of III) endometrioid
adenocarcinoma forming a mass (3.4 x 2.4 x 1.0 cm). The
tumor

invades into the myometrium at a depth of 1.0 cm (total
myometrium

thickness is 1.4 cm). The tumor involves the lower
uterine segment.

The cervix is unremarkable. The myometrium contains a
single
intramural leiomyoma (0.9 cm in greatest dimension).

Ovaries and fallopian tubes, right and left, bilateral
salpingo-oophorectomy: No diagnostic abnormality,
bilaterally.

Lymph nodes, left pelvic, excision: Multiple (9) left
pelvic lymph
nodes are negative for tumor.

Lymph nodes, right pelvic, excision: Multiple (12) right
pelvic
lymph nodes are negative for tumor.

Lymph nodes, bilateral para-aortic, excision: Multiple
(9)
bilateral para-aortic lymph nodes below the inferior
mesenteric
artery are negative for tumor. Tissue submitted as
"bilateral

[page 2 of 2]
para-aortic lymph nodes above the inferior mesenteric
artery" shows
adipose tissue only; no lymph nodes present.

Source: NCI Genomic Data Commons file 8b2e5583-679e-41bc-88d1-4a8fffb978f8 (TCGA-D1-A161.E68A0ED2-CBE3-40A9-8DBF-A3BBC49204DD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).